Somatic mutation profile of tumor specimen 0DSR56 from CCDI case PBCIPG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Pelvis, NOS; Age at diagnosis: 9.1 years (3,338 days).
Specimen 0DSR56: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 93914e93-ae3a-4509-bb08-e965e0d05971.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSR5B (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c83d4d47-c89b-44fc-858f-b95b95e5ede9

The open-access MAF lists 88 somatic variants for this specimen: 64 protein-altering or splice-affecting, 10 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 10, 3'UTR 6, Intron 6, Nonsense Mutation 4, Splice Region 2, 5'Flank 2, Frame Shift Ins 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AATK | c.1823G>A p.R608H (on ENST00000326724 / NM_001080395.3; = p.R505H on NM_004920.2) | Missense Mutation (SNP) | VAF 191/477 reads (40%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs756473019; called by muse, mutect2, varscan2
- ABCC1 | c.3631G>A p.V1211I | Missense Mutation (SNP) | VAF 154/343 reads (45%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.998); catalogued as rs760384485; called by muse, mutect2, varscan2
- ABCC4 | c.155G>A p.R52H | Missense Mutation (SNP) | VAF 21/378 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs142182014; called by muse, mutect2
- CCNP | c.314C>T p.P105L | Missense Mutation (SNP) | VAF 54/816 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as rs760969486, COSV99695775; called by muse, mutect2
- CDH9 | c.854C>A p.T285N | Missense Mutation (SNP) | VAF 116/441 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.124); catalogued as rs1031798308; called by muse, mutect2, varscan2
- CEACAM19 | c.407C>A p.T136N | Missense Mutation (SNP) | VAF 97/454 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV100715498; called by muse, mutect2, varscan2
- CHST3 | c.943G>A p.A315T | Missense Mutation (SNP) | VAF 95/249 reads (38%) | SIFT tolerated (0.53); PolyPhen benign (0.278); catalogued as rs867366138, COSV100910431; called by muse, mutect2, varscan2
- CIT | c.3033G>T p.T1011= | Splice Region (SNP) | VAF 76/288 reads (26%) | catalogued as rs199530958; called by muse, mutect2, varscan2
- CNGA3 | c.1936C>T p.R646C | Missense Mutation (SNP) | VAF 264/880 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as rs753184087, COSV55623211; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL4A2 | c.3664C>G p.P1222A | Missense Mutation (SNP) | VAF 220/534 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.418); catalogued as COSV64628217; called by muse, mutect2, varscan2
- CRTAC1 | c.1237G>A p.D413N | Missense Mutation (SNP) | VAF 105/285 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs772913100; called by muse, mutect2, varscan2
- CYP8B1 | c.620G>A p.R207H | Missense Mutation (SNP) | VAF 109/279 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.809); catalogued as rs368892456; called by muse, mutect2, varscan2
- DGKA | c.329G>A p.R110Q | Missense Mutation (SNP) | VAF 127/459 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.028); catalogued as rs754824628, COSV59387063; called by muse, mutect2, varscan2
- FBXW7 | c.1190G>A p.G397D (on ENST00000281708 / NM_001349798.2; = p.G317D on NM_018315.5) | Missense Mutation (SNP) | VAF 129/270 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55918159; called by muse, mutect2, varscan2
- KRT6B | c.410A>T p.E137V | Missense Mutation (SNP) | VAF 198/1191 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); catalogued as rs1302838812; called by muse, mutect2, varscan2
- LIMCH1 | c.1697C>T p.T566M | Missense Mutation (SNP) | VAF 147/329 reads (45%) | SIFT tolerated (0.26); PolyPhen benign (0.014); catalogued as rs562812091, COSV58285174; called by muse, mutect2, varscan2
- MIS18BP1 | c.2170C>T p.R724W | Missense Mutation (SNP) | VAF 169/418 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as rs1279581268; called by muse, mutect2, varscan2
- NCOR1 | c.5920G>A p.E1974K | Missense Mutation (SNP) | VAF 156/333 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs963357118, COSV51996386; called by muse, mutect2, varscan2
- OR4C11 | c.330C>G p.I110M | Missense Mutation (SNP) | VAF 187/631 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.461); catalogued as COSV56352816, COSV56354100; called by muse, mutect2, varscan2
- OR51G2 | c.944_*2del | Nonstop Mutation (DEL) | VAF 102/367 reads (28%) | catalogued as rs755298876; called by mutect2, pindel, varscan2
- OTOP3 | c.37C>T p.P13S | Missense Mutation (SNP) | VAF 201/465 reads (43%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as rs1225743153; called by muse, mutect2, varscan2
- POM121L12 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 323/1020 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.572); catalogued as COSV68692951, COSV68693360; called by muse, mutect2, varscan2
- SAMD4B | c.1741C>T p.R581W | Missense Mutation (SNP) | VAF 96/465 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); catalogued as rs909285680, COSV58751397; called by muse, mutect2, varscan2
- SERBP1 | c.1151G>T p.R384L (on ENST00000370995 / NM_001018067.2; = p.R363L on NM_015640.4) | Missense Mutation (SNP) | VAF 157/336 reads (47%) | SIFT tolerated (0.63); PolyPhen benign (0.26); catalogued as COSV100769148; called by muse, mutect2, varscan2
- SLC6A2 | c.1684G>A p.A562T | Missense Mutation (SNP) | VAF 241/505 reads (48%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.901); catalogued as rs144701163; called by muse, mutect2, varscan2
- SLC9A2 | c.1136G>A p.G379D | Missense Mutation (SNP) | VAF 209/658 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52134400; called by muse, mutect2, varscan2
- STAB2 | c.4284C>A p.D1428E | Missense Mutation (SNP) | VAF 76/306 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.013); catalogued as rs770648830; called by muse, mutect2, varscan2
- TFRC | c.1547C>T p.P516L | Missense Mutation (SNP) | VAF 73/177 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs761435422; called by muse, mutect2, varscan2
- TOPORS | c.1297G>A p.V433I | Missense Mutation (SNP) | VAF 150/289 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs200877916, COSV62116268; called by muse, mutect2, varscan2
- TRPS1 | c.2084G>C p.R695P (on ENST00000220888 / NM_001330599.2; = p.R708P on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 157/726 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV55234192; called by muse, mutect2, varscan2
- TYK2 | c.1642C>T p.R548C | Missense Mutation (SNP) | VAF 179/832 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); catalogued as rs772532784, COSV53392379; called by muse, mutect2, varscan2
- YTHDC1 | c.151C>T p.R51* | Nonsense Mutation (SNP) | VAF 109/282 reads (39%) | catalogued as COSV60009464; called by muse, mutect2, varscan2
- ABCA9 | c.694A>G p.I232V | Missense Mutation (SNP) | VAF 166/380 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- ACSBG2 | c.146C>T p.T49I | Missense Mutation (SNP) | VAF 128/633 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- ANK3 | c.1300C>T p.L434F | Missense Mutation (SNP) | VAF 61/182 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANKRD30B | c.3605C>A p.A1202D | Missense Mutation (SNP) | VAF 189/418 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); called by muse, varscan2
- ARHGAP26 | c.798C>A p.Y266* | Nonsense Mutation (SNP) | VAF 400/643 reads (62%) | called by muse, mutect2, varscan2
- B4GALNT1 | c.574G>T p.E192* | Nonsense Mutation (SNP) | VAF 172/625 reads (28%) | called by muse, mutect2, varscan2
- BARHL1 | c.679C>T p.Q227* | Nonsense Mutation (SNP) | VAF 116/274 reads (42%) | called by muse, mutect2, varscan2
- C9orf50 | c.1228A>G p.K410E | Missense Mutation (SNP) | VAF 139/314 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- COL4A4 | c.2427A>C p.K809N | Missense Mutation (SNP) | VAF 141/582 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- DNAI1 | c.631T>C p.C211R | Missense Mutation (SNP) | VAF 95/210 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- FGFR4 | c.1880A>G p.K627R | Missense Mutation (SNP) | VAF 305/518 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FZD5 | c.749C>T p.T250M | Missense Mutation (SNP) | VAF 147/533 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GIGYF1 | c.663_667dup p.G223Efs*124 | Frame Shift Ins (INS) | VAF 206/728 reads (28%) | called by mutect2, varscan2
- HDAC11 | c.3-6C>G | Splice Region (SNP) | VAF 93/232 reads (40%) | called by muse, mutect2, varscan2
- JMJD1C | c.2801G>T p.R934L | Missense Mutation (SNP) | VAF 165/402 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- KIF9 | c.120C>A p.D40E | Missense Mutation (SNP) | VAF 160/351 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- KIFC2 | c.1217T>C p.L406P | Missense Mutation (SNP) | VAF 161/700 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MAS1 | c.437A>T p.K146M | Missense Mutation (SNP) | VAF 221/671 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- MON1A | c.931C>T p.R311W | Missense Mutation (SNP) | VAF 127/271 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OBSCN | c.11213G>T p.S3738I | Missense Mutation (SNP) | VAF 178/380 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- PCDHA8 | c.964G>A p.A322T | Missense Mutation (SNP) | VAF 189/761 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- RECK | c.2876G>A p.S959N | Missense Mutation (SNP) | VAF 178/388 reads (46%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- RYR3 | c.5012G>T p.C1671F | Missense Mutation (SNP) | VAF 238/519 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- SIGLEC1 | c.3709G>A p.G1237S | Missense Mutation (SNP) | VAF 110/446 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SIPA1L1 | c.5033A>C p.D1678A | Missense Mutation (SNP) | VAF 268/542 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- SLC38A10 | c.2794A>T p.S932C | Missense Mutation (SNP) | VAF 33/326 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- SPTB | c.469T>A p.F157I | Missense Mutation (SNP) | VAF 184/419 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TMTC3 | c.313G>A p.V105M | Missense Mutation (SNP) | VAF 139/511 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.352); called by muse, mutect2, varscan2
- TRPC6 | c.154G>A p.G52S | Missense Mutation (SNP) | VAF 151/542 reads (28%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- UGT1A1 | c.708A>T p.E236D | Missense Mutation (SNP) | VAF 252/710 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- VANGL2 | c.1075C>A p.L359I | Missense Mutation (SNP) | VAF 108/235 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.457); called by muse, mutect2, varscan2
- ZNF646 | c.3149G>A p.R1050H | Missense Mutation (SNP) | VAF 121/275 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.2484C>G p.V828= | Silent (SNP) | VAF 333/559 reads (60%) | called by muse, mutect2, varscan2
- CLIP3 | c.633G>T p.L211= | Silent (SNP) | VAF 115/422 reads (27%) | called by muse, mutect2, varscan2
- DDAH1 | c.66C>G p.P22= | Silent (SNP) | VAF 156/332 reads (47%) | catalogued as rs750940483; called by muse, mutect2, varscan2
- LRRC74B | c.888C>A p.G296= | Silent (SNP) | VAF 23/367 reads (6%) | called by muse, mutect2
- MUC5AC | c.4909C>T p.L1637= | Silent (SNP) | VAF 154/566 reads (27%) | called by muse, mutect2, varscan2
- MYOCD | c.2448C>G p.P816= | Silent (SNP) | VAF 223/438 reads (51%) | called by muse, mutect2, varscan2
- TPTE | c.999C>A p.I333= (on ENST00000618007 / NM_199261.4; = p.I315= on NM_199259.4) | Silent (SNP) | VAF 50/404 reads (12%) | catalogued as rs759012135; called by mutect2, varscan2
- TTLL12 | c.273C>A p.P91= | Silent (SNP) | VAF 154/358 reads (43%) | called by muse, mutect2, varscan2
- ZNF536 | c.1005C>T p.N335= | Silent (SNP) | VAF 141/628 reads (22%) | catalogued as rs1023728749, COSV100834950, COSV62831700; called by muse, mutect2, varscan2
- ZNF573 | c.651C>A p.T217= (on ENST00000536220 / NM_001172692.1; = p.T159= on NM_152360.3) | Silent (SNP) | VAF 181/744 reads (24%) | called by muse, mutect2, varscan2
- AC018647.1 | n.1680+383G>A | Intron (SNP) | VAF 120/319 reads (38%) | called by muse, mutect2, varscan2
- ARHGEF9 | chrX:63755179 G>A | 5'Flank (SNP) | VAF 138/155 reads (89%) | called by muse, mutect2, varscan2
- CEP104 | c.*50G>T | 3'UTR (SNP) | VAF 57/123 reads (46%) | called by muse, mutect2, varscan2
- CFAP46 | c.2924+38C>A | Intron (SNP) | VAF 145/280 reads (52%) | catalogued as rs910396301; called by muse, mutect2, varscan2
- FNTA | c.*9A>G | 3'UTR (SNP) | VAF 131/578 reads (23%) | catalogued as rs1209959529; called by muse, mutect2, varscan2
- KCNK7 | chr11:65595833 G>T | 5'Flank (SNP) | VAF 11/223 reads (5%) | called by muse, mutect2
- LILRB5 | c.1576+44C>A | Intron (SNP) | VAF 162/546 reads (30%) | called by muse, mutect2, varscan2
- MAST3 | c.*259_*264del | 3'UTR (DEL) | VAF 26/236 reads (11%) | catalogued as rs1351059621; called by pindel, varscan2
- MPV17 | c.409-64C>A | Intron (SNP) | VAF 72/197 reads (37%) | called by muse, mutect2, varscan2
- PMM2 | c.*8G>A | 3'UTR (SNP) | VAF 119/233 reads (51%) | catalogued as COSV51633764; called by muse, mutect2, varscan2
- PXDNL | c.4017-65_4017-63del | Intron (DEL) | VAF 30/158 reads (19%) | called by pindel, varscan2
- SLC6A1 | c.1191+82T>A | Intron (SNP) | VAF 29/68 reads (43%) | called by muse, mutect2, varscan2
- SOX8 | c.*4C>A | 3'UTR (SNP) | VAF 110/220 reads (50%) | called by muse, mutect2, varscan2
- TBX1 | c.*89T>C | 3'UTR (SNP) | VAF 85/156 reads (54%) | called by muse, mutect2, varscan2
